Somatic mutation profile of tumor specimen TCGA-VQ-A94U-01A (aliquot TCGA-VQ-A94U-01A-12D-A410-08) from TCGA case TCGA-VQ-A94U, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Signet ring cell carcinoma; Tissue or organ of origin: Gastric antrum; AJCC pathologic stage: Stage IIB; Tumor grade: G3; Age at diagnosis: 71.0 years (25,925 days).
Specimen TCGA-VQ-A94U-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4b85fe05-f4e5-41e5-b6c3-b522cc4522bd.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-VQ-A94U-10A (Blood Derived Normal), aliquot TCGA-VQ-A94U-10A-01D-A413-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1e07c69c-4bd9-4a84-b615-7a6b32db43ba

The open-access MAF lists 163 somatic variants for this specimen: 122 protein-altering or splice-affecting, 38 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 104, Silent 38, Nonsense Mutation 7, Frame Shift Del 4, Frame Shift Ins 4, Splice Site 2, RNA 2, In Frame Del 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ATP8B1 | c.614dup p.N205Kfs*2 | Frame Shift Ins (INS) | VAF 20/32 reads (63%) | catalogued as rs761784230; ClinVar: pathogenic; called by mutect2, varscan2
- RTEL1 | c.2957G>A p.R986Q | Missense Mutation (SNP) | VAF 35/122 reads (29%) | SIFT tolerated (0.37); PolyPhen benign (0.003); catalogued as rs146221660; ClinVar: uncertain significance / pathogenic; called by muse, mutect2, varscan2
- SYNGAP1 | c.427C>T p.R143* | Nonsense Mutation (SNP) | VAF 12/43 reads (28%) | catalogued as rs397514741, CM1314734, COSV99537990; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ACACB | c.4862G>C p.R1621P | Missense Mutation (SNP) | VAF 43/179 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs143327495, COSV100622465; called by muse, mutect2, varscan2
- ACSM2B | c.1651C>G p.P551A | Missense Mutation (SNP) | VAF 64/298 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100312409; called by muse, mutect2, varscan2
- ACTRT1 | c.320T>C p.L107P | Missense Mutation (SNP) | VAF 109/273 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV64418999, COSV64419064; called by muse, mutect2, varscan2
- APOB | c.6943G>T p.E2315* | Nonsense Mutation (SNP) | VAF 26/132 reads (20%) | catalogued as COSV99264223; called by muse, mutect2, varscan2
- BAALC | c.401C>T p.T134I (on ENST00000297574 / NM_001364874.1; = p.T99I on NM_024812.3) | Missense Mutation (SNP) | VAF 22/108 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.446); catalogued as COSV99883266; called by muse, mutect2, varscan2
- BABAM1 | c.458C>T p.T153M | Missense Mutation (SNP) | VAF 19/86 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.009); catalogued as rs750288594, COSV100845712; called by muse, mutect2, varscan2
- BCLAF1 | c.1184A>G p.N395S | Missense Mutation (SNP) | VAF 17/114 reads (15%) | SIFT tolerated (0.91); PolyPhen benign (0.01); catalogued as rs757818777, COSV100786442; called by muse, mutect2, varscan2
- BCLAF3 | c.404A>G p.Q135R | Missense Mutation (SNP) | VAF 61/82 reads (74%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.89); catalogued as COSV100503240; called by muse, mutect2, varscan2
- BMPER | c.2005T>G p.L669V | Missense Mutation (SNP) | VAF 50/144 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.489); catalogued as COSV99779119; called by muse, mutect2, varscan2
- C8orf34 | c.838G>A p.D280N | Missense Mutation (SNP) | VAF 30/72 reads (42%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.995); catalogued as COSV100444942; called by muse, mutect2, varscan2
- CASZ1 | c.2303C>T p.P768L | Missense Mutation (SNP) | VAF 10/72 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.052); catalogued as COSV100680887; called by muse, mutect2, varscan2
- CD53 | c.515C>T p.A172V | Missense Mutation (SNP) | VAF 41/86 reads (48%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as rs531836002, COSV54761209; called by muse, mutect2, varscan2
- CEP128 | c.955G>T p.A319S | Missense Mutation (SNP) | VAF 31/100 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.113); catalogued as COSV99382946; called by muse, mutect2, varscan2
- CFAP70 | c.1145T>A p.F382Y | Missense Mutation (SNP) | VAF 32/164 reads (20%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.601); catalogued as COSV100160277; called by muse, mutect2, varscan2
- CFHR1 | c.733G>A p.G245S | Missense Mutation (SNP) | VAF 24/143 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100258676; called by muse, mutect2, varscan2
- CPA2 | c.1110T>G p.D370E | Missense Mutation (SNP) | VAF 12/73 reads (16%) | SIFT tolerated (0.1); PolyPhen benign (0.015); catalogued as COSV99743837; called by muse, mutect2, varscan2
- CTNND2 | c.1231C>T p.R411W | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1490647469, COSV58864690; called by muse, mutect2, varscan2
- CYRIA | c.710+1G>A p.X237_splice | Splice Site (SNP) | VAF 26/109 reads (24%) | catalogued as COSV62864419, COSV62865524; called by muse, mutect2, varscan2
- CYRIA | c.187C>T p.R63* | Nonsense Mutation (SNP) | VAF 50/224 reads (22%) | catalogued as rs1161086604, COSV100838237; called by muse, varscan2
- DDI1 | c.88T>C p.F30L | Missense Mutation (SNP) | VAF 42/182 reads (23%) | SIFT tolerated (0.33); PolyPhen benign (0.137); catalogued as COSV56368251, COSV56370169; called by muse, mutect2, varscan2
- DDX56 | c.1115G>T p.R372L | Missense Mutation (SNP) | VAF 11/59 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as COSV99345963; called by muse, mutect2, varscan2
- DPYSL4 | c.859G>A p.G287S | Missense Mutation (SNP) | VAF 39/118 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs754068086, COSV58305995; called by muse, mutect2, varscan2
- DSEL | c.3246C>G p.N1082K | Missense Mutation (SNP) | VAF 24/74 reads (32%) | SIFT tolerated (0.91); PolyPhen benign (0.046); catalogued as rs773918044, COSV100025366; called by muse, mutect2, varscan2
- EDIL3 | c.1028C>T p.T343M | Missense Mutation (SNP) | VAF 17/70 reads (24%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.951); catalogued as rs757863733, COSV56879041; called by muse, mutect2, varscan2
- EPRS1 | c.3304G>T p.A1102S | Missense Mutation (SNP) | VAF 30/126 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65101538; called by muse, mutect2, varscan2
- F8 | c.1675G>A p.E559K | Missense Mutation (SNP) | VAF 34/104 reads (33%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.811); catalogued as CM108712, COSV100811329; called by muse, mutect2, varscan2
- FAT2 | c.2902G>A p.A968T | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT tolerated (0.52); PolyPhen benign (0.36); catalogued as rs149531804; called by muse, mutect2, varscan2
- FCGRT | c.1007G>A p.R336H | Missense Mutation (SNP) | VAF 34/212 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.011); catalogued as rs756324491, COSV99571212; called by muse, mutect2, varscan2
- FEM1C | c.807G>A p.W269* | Nonsense Mutation (SNP) | VAF 25/77 reads (32%) | catalogued as COSV99174354; called by muse, mutect2, varscan2
- FLG | c.8580A>C p.E2860D | Missense Mutation (SNP) | VAF 127/1211 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.278); catalogued as COSV64243105; called by muse, mutect2, varscan2
- FLG | c.3643A>C p.S1215R | Missense Mutation (SNP) | VAF 117/593 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.307); catalogued as COSV100910503, COSV64238953, COSV64251096; called by muse, mutect2, varscan2
- FLNA | c.3547G>A p.V1183M | Missense Mutation (SNP) | VAF 20/57 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100774377, COSV61036445; called by muse, mutect2, varscan2
- GDAP1L1 | c.83C>T p.A28V | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0); catalogued as COSV100697496, COSV100697661; called by muse, mutect2, varscan2
- GFM2 | c.106A>G p.K36E | Missense Mutation (SNP) | VAF 33/109 reads (30%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.098); catalogued as COSV99714130; called by muse, mutect2, varscan2
- GLRB | c.215G>A p.R72K | Missense Mutation (SNP) | VAF 4/49 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); catalogued as COSV100029536; called by muse, mutect2
- GPR139 | c.682G>A p.A228T | Missense Mutation (SNP) | VAF 28/91 reads (31%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs1314429704, COSV58502491; called by muse, mutect2, varscan2
- GTF2IRD2 | c.1664C>T p.T555M | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); catalogued as rs1377562943, COSV100736394; called by mutect2, varscan2
- GTF2IRD2B | c.1664C>T p.T555M | Missense Mutation (SNP) | VAF 10/76 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs782314107; called by mutect2, varscan2
- HBD | c.173A>C p.N58T | Missense Mutation (SNP) | VAF 22/77 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53083619; called by muse, mutect2, varscan2
- HECW2 | c.2216G>A p.R739Q | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.968); catalogued as rs201414655, COSV99647544; called by muse, mutect2, varscan2
- HLA-E | c.1058C>G p.S353C | Missense Mutation (SNP) | VAF 18/79 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.971); catalogued as COSV100931889; called by muse, mutect2, varscan2
- INTS13 | c.458G>A p.R153H | Missense Mutation (SNP) | VAF 13/82 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.005); catalogued as rs371059413, COSV99677708; called by muse, mutect2, varscan2
- ITGA5 | c.1676G>A p.R559Q | Missense Mutation (SNP) | VAF 11/63 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99516429; called by muse, mutect2, varscan2
- JPH2 | c.1609C>T p.R537C | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.366); catalogued as rs1358759814, COSV100881639; called by muse, mutect2
- KCNK2 | c.1094T>A p.L365H (on ENST00000444842 / NM_001017425.3; = p.L350H on NM_014217.4) | Missense Mutation (SNP) | VAF 17/70 reads (24%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.928); catalogued as COSV101221931; called by muse, mutect2, varscan2
- KIF17 | c.2803C>T p.R935C | Missense Mutation (SNP) | VAF 48/160 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as COSV99928673; called by muse, mutect2, varscan2
- LCE2C | c.128C>T p.A43V | Missense Mutation (SNP) | VAF 82/272 reads (30%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.025); catalogued as COSV100909400; called by muse, mutect2, varscan2
- LRRK2 | c.1803A>C p.E601D | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT tolerated (0.18); PolyPhen benign (0.015); catalogued as COSV100109497; called by muse, mutect2
- LUZP1 | c.1915A>C p.S639R | Missense Mutation (SNP) | VAF 67/267 reads (25%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.555); catalogued as COSV100034623; called by muse, mutect2, varscan2
- MDN1 | c.15811G>A p.D5271N | Missense Mutation (SNP) | VAF 38/148 reads (26%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.862); catalogued as rs947039732, COSV101020899; called by muse, mutect2, varscan2
- MINK1 | c.2927G>A p.G976D | Missense Mutation (SNP) | VAF 30/111 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.135); catalogued as COSV99544634; called by muse, mutect2, varscan2
- MYCT1 | c.155A>C p.N52T | Missense Mutation (SNP) | VAF 12/65 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100924041; called by muse, mutect2, varscan2
- MYH3 | c.2111G>A p.R704H | Missense Mutation (SNP) | VAF 37/96 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as rs745848183, COSV99877869; called by muse, mutect2, varscan2
- NRAP | c.5164G>A p.V1722I (on ENST00000359988 / NM_001322945.2; = p.V1687I on NM_006175.4) | Missense Mutation (SNP) | VAF 28/161 reads (17%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.015); catalogued as rs779673504, COSV63494218; called by muse, mutect2, varscan2
- OR10G9 | c.503G>T p.C168F | Missense Mutation (SNP) | VAF 49/243 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66685760; called by muse, mutect2, varscan2
- OR4X2 | c.240A>C p.E80D | Missense Mutation (SNP) | VAF 31/167 reads (19%) | SIFT tolerated (0.11); PolyPhen benign (0.015); catalogued as COSV100183178; called by muse, mutect2, varscan2
- OR52D1 | c.718G>T p.A240S | Missense Mutation (SNP) | VAF 28/94 reads (30%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.822); catalogued as COSV100495164; called by muse, mutect2, varscan2
- OR5L2 | c.32A>G p.E11G | Missense Mutation (SNP) | VAF 50/201 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.357); catalogued as COSV65723460, COSV65724594, COSV65724996; called by muse, mutect2, varscan2
- OR8B2 | c.809G>A p.G270E | Missense Mutation (SNP) | VAF 33/128 reads (26%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.831); catalogued as COSV66664176; called by muse, mutect2, varscan2
- PAK2 | c.1198C>T p.R400C | Missense Mutation (SNP) | VAF 22/84 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100505952; called by muse, mutect2, varscan2
- PCDH17 | c.2923G>T p.V975L | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.076); catalogued as COSV100931485; called by muse, mutect2, varscan2
- PCDH18 | c.3092G>A p.R1031Q | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT tolerated (0.59); PolyPhen benign (0.017); catalogued as rs1368391396, COSV100787105, COSV61268332; called by muse, mutect2, varscan2
- PCDHA9 | c.1313C>T p.T438M | Missense Mutation (SNP) | VAF 40/124 reads (32%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.475); catalogued as rs782596330, COSV65326310; called by muse, mutect2, varscan2
- PCDHGA2 | c.966G>T p.Q322H | Missense Mutation (SNP) | VAF 112/179 reads (63%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.076); catalogued as COSV99533133; called by muse, mutect2, varscan2
- PCDHGA4 | c.2260C>T p.R754C | Missense Mutation (SNP) | VAF 16/49 reads (33%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.901); catalogued as COSV53892016, COSV99533134; called by muse, mutect2, varscan2
- PCDHGA5 | c.1844G>T p.G615V | Missense Mutation (SNP) | VAF 32/106 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.952); catalogued as COSV53992591, COSV99533135; called by muse, mutect2, varscan2
- PCDHGB3 | c.100C>T p.R34C | Missense Mutation (SNP) | VAF 17/62 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); catalogued as rs1430797606, COSV53906319; called by muse, mutect2, varscan2
- PNLIP | c.54A>C p.E18D | Missense Mutation (SNP) | VAF 14/113 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.046); catalogued as COSV65040728; called by muse, mutect2, varscan2
- POTEE | c.2384G>A p.R795H | Missense Mutation (SNP) | VAF 30/118 reads (25%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.478); catalogued as rs748017694, COSV100388449, COSV58239217; called by muse, mutect2, varscan2
- PREPL | c.2030C>T p.T677I | Missense Mutation (SNP) | VAF 21/104 reads (20%) | SIFT tolerated (0.58); PolyPhen benign (0.001); catalogued as COSV99575987; called by muse, mutect2, varscan2
- PRF1 | c.767A>C p.D256A | Missense Mutation (SNP) | VAF 18/98 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.727); catalogued as COSV100942547; called by muse, mutect2, varscan2
- PROX1 | c.751C>T p.R251C | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99798820; called by muse, mutect2, varscan2
- PSG1 | c.461G>A p.S154N | Missense Mutation (SNP) | VAF 47/230 reads (20%) | SIFT tolerated (0.91); PolyPhen possibly damaging (0.649); catalogued as COSV99738982; called by muse, mutect2, varscan2
- PTGIS | c.1133G>A p.R378Q | Missense Mutation (SNP) | VAF 16/85 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs779113385, COSV54836651; called by muse, mutect2, varscan2
- PTPRF | c.5060G>A p.R1687H | Missense Mutation (SNP) | VAF 21/77 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs1387514159, COSV100740710; called by muse, mutect2, varscan2
- PYHIN1 | c.104T>G p.L35R | Missense Mutation (SNP) | VAF 19/77 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100932333; called by muse, mutect2, varscan2
- RAB23 | c.222T>G p.I74M | Missense Mutation (SNP) | VAF 29/98 reads (30%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.793); catalogued as COSV100443746; called by muse, mutect2, varscan2
- RASGRF2 | c.865G>A p.V289I | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.479); catalogued as rs747963579, COSV54131808; called by muse, mutect2
- RFLNA | c.493C>T p.R165C (on ENST00000546355 / NM_001365156.1; = p.R84C on NM_181709.4) | Missense Mutation (SNP) | VAF 30/126 reads (24%) | SIFT tolerated (0.07); PolyPhen benign (0.001); catalogued as rs150991901; called by muse, mutect2, varscan2
- RFX1 | c.229G>A p.E77K | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.453); catalogued as COSV99585871; called by muse, mutect2, varscan2
- RGS7BP | c.390C>A p.C130* | Nonsense Mutation (SNP) | VAF 16/89 reads (18%) | catalogued as COSV100470500; called by muse, mutect2, varscan2
- RNF123 | c.380C>T p.T127I | Missense Mutation (SNP) | VAF 97/295 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.283); catalogued as COSV100570364; called by muse, mutect2, varscan2
- ROR1 | c.733C>T p.R245C | Missense Mutation (SNP) | VAF 46/155 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs528483506, COSV100935055; called by muse, mutect2, varscan2
- SAMD10 | c.155C>T p.P52L | Missense Mutation (SNP) | VAF 12/65 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.107); catalogued as rs774160755, COSV99411574; called by muse, mutect2, varscan2
- SAP30L | c.436C>T p.H146Y | Missense Mutation (SNP) | VAF 67/214 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99770359; called by muse, mutect2, varscan2
- SCG2 | c.1195T>G p.L399V | Missense Mutation (SNP) | VAF 11/65 reads (17%) | SIFT tolerated (0.36); PolyPhen benign (0.003); catalogued as COSV59538910, COSV59540439; called by muse, mutect2, varscan2
- SERTAD2 | c.758C>T p.T253M | Missense Mutation (SNP) | VAF 16/83 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs762462704, COSV100512132; called by muse, mutect2, varscan2
- SFTPA2 | c.157G>C p.D53H | Missense Mutation (SNP) | VAF 25/118 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.951); catalogued as COSV100958721; called by muse, mutect2, varscan2
- SH3RF3 | c.1706C>A p.A569D | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT tolerated (0.07); PolyPhen benign (0.317); catalogued as COSV100512472; called by muse, mutect2, varscan2
- SLC32A1 | c.503C>T p.A168V | Missense Mutation (SNP) | VAF 15/79 reads (19%) | SIFT tolerated (0.14); PolyPhen benign (0.301); catalogued as rs968205956, COSV54146280, COSV99462168; called by muse, mutect2, varscan2
- SLC6A7 | c.778C>T p.R260C | Missense Mutation (SNP) | VAF 20/67 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs145923003; called by muse, mutect2, varscan2
- SNAI1 | c.772G>A p.G258S | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs151036730; called by muse, mutect2, varscan2
- SSMEM1 | c.173C>A p.A58D | Missense Mutation (SNP) | VAF 20/80 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.847); catalogued as COSV52833096, COSV99927627; called by muse, mutect2, varscan2
- STRA8 | c.733-2A>G p.X245_splice (on ENST00000275764; = p.X223_splice on NM_182489.2) | Splice Site (SNP) | VAF 12/55 reads (22%) | catalogued as rs780235054, COSV99312283; called by muse, mutect2, varscan2
- SYT15 | c.232G>A p.V78M | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT tolerated (0.09); PolyPhen benign (0.015); catalogued as rs376965392; called by muse, mutect2, varscan2
- TAFA2 | c.169A>C p.K57Q | Missense Mutation (SNP) | VAF 12/57 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.966); catalogued as COSV101353013, COSV69179114; called by muse, mutect2, varscan2
- TLE4 | c.1014C>A p.N338K | Missense Mutation (SNP) | VAF 26/89 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.001); catalogued as COSV99511434; called by muse, mutect2, varscan2
- TMEM177 | c.692T>C p.L231P | Missense Mutation (SNP) | VAF 23/72 reads (32%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.735); catalogued as COSV99733553; called by muse, mutect2, varscan2
- TNFRSF10B | c.1235_1236del p.R412Tfs*7 | Frame Shift Del (DEL) | VAF 42/126 reads (33%) | catalogued as rs1563303865; called by pindel, varscan2
- TP53 | c.625A>T p.R209* | Nonsense Mutation (SNP) | VAF 33/53 reads (62%) | catalogued as rs1429743956, CM971504, COSV52741360, COSV52840233, COSV53599366; called by muse, mutect2, varscan2
- TRIM63 | c.793C>T p.Q265* | Nonsense Mutation (SNP) | VAF 20/88 reads (23%) | catalogued as COSV100958139; called by muse, mutect2, varscan2
- TRPS1 | c.1996C>T p.H666Y (on ENST00000220888 / NM_001330599.2; = p.H679Y on NM_014112.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 20/59 reads (34%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0.012); catalogued as COSV99629086; called by muse, mutect2, varscan2
- TTPA | c.527C>T p.A176V | Missense Mutation (SNP) | VAF 19/68 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as COSV99478427; called by muse, mutect2, varscan2
- TYK2 | c.1123G>A p.A375T | Missense Mutation (SNP) | VAF 24/86 reads (28%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs773725258, COSV99314404; called by muse, mutect2, varscan2
- UGT3A1 | c.1350C>A p.S450R | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT tolerated (0.19); PolyPhen benign (0.155); catalogued as COSV99954425; called by muse, mutect2, varscan2
- WBP4 | c.337A>C p.K113Q | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.997); catalogued as COSV101069230; called by muse, mutect2, varscan2
- WDR46 | c.1828C>T p.R610C | Missense Mutation (SNP) | VAF 53/194 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs148252283; called by muse, mutect2, varscan2
- XIRP2 | c.419A>T p.K140I (on ENST00000628543; = p.K315I on NM_152381.6) | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT tolerated (0.09); PolyPhen benign (0.094); catalogued as COSV99739652; called by muse, mutect2, varscan2
- XIRP2 | c.3678A>T p.E1226D (on ENST00000628543; = p.E1401D on NM_152381.6) | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT tolerated (0.37); PolyPhen benign (0.003); catalogued as COSV54696788, COSV54722905, COSV99739657; called by muse, mutect2, varscan2
- XPO6 | c.2371G>A p.V791I | Missense Mutation (SNP) | VAF 24/114 reads (21%) | SIFT tolerated (0.83); PolyPhen benign (0.023); catalogued as rs11557749, COSV100484785; called by muse, mutect2, varscan2
- ZNF613 | c.1208A>G p.N403S (on ENST00000293471 / NM_001031721.4; = p.N367S on NM_024840.4) | Missense Mutation (SNP) | VAF 77/125 reads (62%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV99522864; called by muse, mutect2, varscan2
- AMOTL2 | c.597_611del p.P200_P204del | In Frame Del (DEL) | VAF 17/66 reads (26%) | called by mutect2, pindel, varscan2
- BOD1 | c.486dup p.A163Sfs*34 | Frame Shift Ins (INS) | VAF 16/86 reads (19%) | called by mutect2, pindel, varscan2
- HLA-C | c.482_486dup p.A163Tfs*20 | Frame Shift Ins (INS) | VAF 8/62 reads (13%) | called by mutect2, pindel
- IQCA1 | c.1980dup p.H661Tfs*13 | Frame Shift Ins (INS) | VAF 13/53 reads (25%) | called by mutect2, pindel, varscan2
- NELL2 | c.2392del p.Q798Sfs*30 | Frame Shift Del (DEL) | VAF 14/57 reads (25%) | called by mutect2, pindel, varscan2
- PRAMEF18 | c.624A>T p.Q208H | Missense Mutation (SNP) | VAF 108/1020 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.097); called by muse, mutect2, varscan2
- RAB4A | c.587_608del p.D196Gfs*35 | Frame Shift Del (DEL) | VAF 18/92 reads (20%) | called by mutect2, pindel
- USP47 | c.2201_2244del p.V734Dfs*10 (on ENST00000399455 / NM_001372095.1; = p.V646Dfs*10 on NM_017944.4 and 3 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 10/42 reads (24%) | called by mutect2, pindel
- ABCA12 | c.4278C>T p.H1426= (on ENST00000272895 / NM_173076.3; = p.H1108= on NM_015657.3) | Silent (SNP) | VAF 32/93 reads (34%) | catalogued as rs771769694, COSV99788816; called by muse, mutect2, varscan2
- APBA2 | c.543A>G p.E181= | Silent (SNP) | VAF 7/26 reads (27%) | catalogued as COSV101381989; called by muse, mutect2, varscan2
- ATL3 | c.1116G>A p.G372= | Silent (SNP) | VAF 8/40 reads (20%) | catalogued as COSV100219744; called by muse, mutect2, varscan2
- BCL2L12 | c.423C>T p.S141= | Silent (SNP) | VAF 54/145 reads (37%) | catalogued as COSV99880930; called by muse, mutect2, varscan2
- BMP7 | c.873C>T p.I291= | Silent (SNP) | VAF 23/100 reads (23%) | catalogued as COSV101215646; called by muse, mutect2, varscan2
- CAMTA1 | c.4158C>T p.C1386= | Silent (SNP) | VAF 9/38 reads (24%) | catalogued as rs780992004, COSV57883289; called by muse, mutect2, varscan2
- CLSTN1 | c.1098C>T p.N366= (on ENST00000377298 / NM_001009566.3; = p.N356= on NM_014944.4) | Silent (SNP) | VAF 7/46 reads (15%) | catalogued as rs754180612, COSV100790494; called by muse, mutect2, varscan2
- DHRS13 | c.9G>A p.A3= | Silent (SNP) | VAF 7/12 reads (58%) | catalogued as COSV100241634; called by muse, mutect2, varscan2
- FER1L6 | c.3141C>T p.F1047= | Silent (SNP) | VAF 8/90 reads (9%) | catalogued as rs541571610, COSV67548255; called by muse, mutect2
- FPGT | c.843C>T p.V281= | Silent (SNP) | VAF 17/79 reads (22%) | catalogued as COSV100907076; called by muse, mutect2, varscan2
- GIPR | c.876C>G p.V292= | Silent (SNP) | VAF 63/329 reads (19%) | catalogued as COSV54423949; called by muse, mutect2, varscan2
- GPX5 | c.537C>A p.I179= | Silent (SNP) | VAF 58/118 reads (49%) | catalogued as COSV101297248, COSV69079347; called by muse, mutect2, varscan2
- HMCN1 | c.5775A>C p.G1925= | Silent (SNP) | VAF 9/67 reads (13%) | catalogued as COSV99625456; called by muse, mutect2, varscan2
- INA | c.279C>T p.N93= | Silent (SNP) | VAF 7/45 reads (16%) | catalogued as rs898863226, COSV100878589; called by muse, varscan2
- IRGC | c.1053C>T p.S351= | Silent (SNP) | VAF 10/46 reads (22%) | catalogued as rs543218904, COSV54982662, COSV54983610; called by muse, mutect2, varscan2
- ITGAX | c.3477G>T p.P1159= | Silent (SNP) | VAF 21/110 reads (19%) | catalogued as COSV51641243, COSV99191517; called by muse, mutect2
- ITPR1 | c.6279G>A p.S2093= (on ENST00000354582; = p.S2038= on NM_002222.7) | Silent (SNP) | VAF 18/75 reads (24%) | catalogued as rs771768628, COSV56967795; called by muse, mutect2, varscan2
- LRRK2 | c.414C>T p.T138= | Silent (SNP) | VAF 7/31 reads (23%) | catalogued as COSV100109494; called by muse, mutect2, varscan2
- LRRTM1 | c.963C>T p.N321= | Silent (SNP) | VAF 12/47 reads (26%) | catalogued as COSV99702017; called by muse, mutect2, varscan2
- MYT1L | c.2436C>T p.G812= | Silent (SNP) | VAF 16/72 reads (22%) | catalogued as rs372483670; called by muse, mutect2, varscan2
- OGDHL | c.2745C>T p.R915= | Silent (SNP) | VAF 30/122 reads (25%) | catalogued as COSV100934220; called by muse, mutect2, varscan2
- PCDHGA1 | c.1995C>T p.A665= | Silent (SNP) | VAF 22/89 reads (25%) | catalogued as rs1261271059, COSV100965940; called by muse, mutect2, varscan2
- PLXDC2 | c.1539A>G p.E513= | Silent (SNP) | VAF 20/102 reads (20%) | catalogued as COSV101022822, COSV65902507; called by muse, mutect2, varscan2
- PLXNC1 | c.3324G>A p.V1108= | Silent (SNP) | VAF 13/62 reads (21%) | catalogued as rs1348186115, COSV99312600; called by muse, mutect2, varscan2
- RUFY3 | c.594C>T p.A198= | Silent (SNP) | VAF 27/100 reads (27%) | catalogued as COSV99886990; called by muse, mutect2, varscan2
- SLC39A10 | c.174T>C p.N58= | Silent (SNP) | VAF 10/35 reads (29%) | catalogued as COSV100660538; called by muse, mutect2, varscan2
- SLC6A11 | c.798G>A p.L266= | Silent (SNP) | VAF 51/172 reads (30%) | catalogued as COSV54396408; called by muse, mutect2, varscan2
- TAF1L | c.537A>G p.E179= | Silent (SNP) | VAF 19/56 reads (34%) | catalogued as COSV99644255; called by muse, mutect2, varscan2
- TAS2R7 | c.615C>T p.I205= | Silent (SNP) | VAF 10/48 reads (21%) | catalogued as rs751352517, COSV99553647; called by muse, mutect2, varscan2
- TTF1 | c.1923G>T p.T641= | Silent (SNP) | VAF 18/30 reads (60%) | catalogued as COSV100524532; called by muse, mutect2, varscan2
- URB2 | c.468G>A p.S156= | Silent (SNP) | VAF 20/77 reads (26%) | catalogued as rs779255675, COSV99270798, COSV99271422; called by muse, mutect2, varscan2
- USP43 | c.1374C>T p.S458= | Silent (SNP) | VAF 8/23 reads (35%) | catalogued as rs755835354, COSV99556473; called by muse, mutect2, varscan2
- VPS13D | c.6852T>C p.C2284= | Silent (SNP) | VAF 7/60 reads (12%) | catalogued as COSV99165719; called by muse, mutect2, varscan2
- XKR6 | c.1881C>T p.D627= | Silent (SNP) | VAF 48/137 reads (35%) | catalogued as rs200925376, COSV100440353; called by muse, mutect2, varscan2
- ZEB2 | c.2178T>C p.S726= | Silent (SNP) | VAF 38/165 reads (23%) | catalogued as COSV100355335; called by muse, mutect2, varscan2
- ZNF585B | c.996G>A p.G332= | Silent (SNP) | VAF 43/243 reads (18%) | catalogued as COSV100459338; called by muse, mutect2, varscan2
- ZNF672 | c.921C>G p.G307= | Silent (SNP) | VAF 6/42 reads (14%) | catalogued as COSV100129081, COSV60638339; called by muse, mutect2
- ZNF697 | c.1410C>T p.C470= | Silent (SNP) | VAF 7/33 reads (21%) | catalogued as rs200313032, COSV101360079; called by muse, mutect2, varscan2
- FAM74A3 | n.397T>C | RNA (SNP) | VAF 31/153 reads (20%) | called by muse, mutect2, varscan2
- FRMPD2B | n.1224A>C | RNA (SNP) | VAF 41/178 reads (23%) | called by mutect2, varscan2
- NEBL | c.164+25938A>C | Intron (SNP) | VAF 13/111 reads (12%) | catalogued as COSV101008696; called by muse, mutect2, varscan2
